Somatic mutation profile of tumor specimen ALCH-B1ON-TTP1-A (aliquot ALCH-B1ON-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1ON, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.2 years (26,728 days).
Specimen ALCH-B1ON-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e9278a-ab61-4d70-a5ec-ae4fdbcbc5cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ON-NB1-A (Blood Derived Normal), aliquot ALCH-B1ON-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fad0f81-cd6b-4569-bbed-95f420afed98

The open-access MAF lists 517 somatic variants for this specimen: 366 protein-altering or splice-affecting, 86 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 86, Intron 29, Nonsense Mutation 18, RNA 12, Splice Site 10, 3'UTR 9, Frame Shift Del 7, Frame Shift Ins 6, 5'Flank 6, 3'Flank 5, Splice Region 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGB | c.34C>G p.H12D | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.378); catalogued as COSV58855743; called by muse, mutect2, varscan2
- AOC1 | c.1413del p.N472Tfs*3 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as COSV100710924; called by mutect2, pindel, varscan2
- APPBP2 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV50027802; called by muse, mutect2
- ASCL1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs754672998; called by muse, mutect2, varscan2
- ASMT | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as rs1411192017; called by muse, mutect2, varscan2
- ATAD3C | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs542001681, COSV66483045; called by muse, mutect2, varscan2
- ATXN1 | c.2183A>G p.N728S | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1394519805; called by muse, mutect2, varscan2
- CABYR | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV59111008; called by muse, mutect2, varscan2
- CACNA1S | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs138205421, COSV104423938; called by muse, mutect2, varscan2
- CD163L1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603675; called by muse, mutect2, varscan2
- CDH8 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV54880222; called by muse, mutect2, varscan2
- CENPF | c.4380G>T p.L1460F | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.94); catalogued as COSV100871584; called by muse, mutect2, varscan2
- CHST15 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 57/324 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV60565015, COSV60566151; called by muse, mutect2, varscan2
- COL6A6 | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs907630509; called by muse, mutect2, varscan2
- CYP3A5 | c.1414-1G>A p.X472_splice | Splice Site (SNP) | VAF 29/166 reads (17%) | catalogued as rs1441700361; called by muse, mutect2, varscan2
- DDX51 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs780739881, COSV57957056; called by muse, mutect2, varscan2
- DLL4 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs781379364, COSV51061089, COSV51074572; called by muse, mutect2
- DPPA2 | c.488A>T p.Y163F | Missense Mutation (SNP) | VAF 93/589 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101524771; called by muse, mutect2, varscan2
- DSC1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780433012; called by muse, mutect2
- DSP | c.8402G>A p.R2801H | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs763712887, COSV60939548; called by muse, mutect2, varscan2
- ENPP2 | c.1059C>G p.N353K (on ENST00000075322 / NM_001040092.3; = p.N405K on NM_006209.5) | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs368155133; called by muse, mutect2, varscan2
- ESYT2 | c.1239C>A p.D413E (on ENST00000613624; = p.D337E on NM_020728.3) | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762794309; called by muse, mutect2, varscan2
- EYS | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV60997507, COSV60998944; called by muse, mutect2, varscan2
- FAM90A1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 30/229 reads (13%) | catalogued as rs1309098673; called by muse, mutect2, varscan2
- GAA | c.1981T>G p.W661G | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM082750; called by muse, mutect2, varscan2
- GABRR3 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.044); catalogued as rs1328254689; called by muse, mutect2, varscan2
- GAR1 | c.623G>T p.R208I | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV56993320; called by muse, mutect2, varscan2
- GOLGA8S | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV73788187; called by mutect2, varscan2
- GRB7 | c.1453-2A>G p.X485_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100485377; called by muse, mutect2, varscan2
- GRM3 | c.2310C>A p.F770L | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV64468808, COSV64480208; called by muse, mutect2, varscan2
- GRWD1 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53520931; called by muse, mutect2, varscan2
- H1-4 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 99/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104388638; called by muse, mutect2, varscan2
- HCN1 | c.1282C>A p.R428S | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV57528161; called by muse, mutect2, varscan2
- HTATSF1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV54477632; called by muse, mutect2, varscan2
- IFT88 | c.1856A>G p.Y619C (on ENST00000319980 / NM_001318493.2; = p.Y610C on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs373094049; called by mutect2, varscan2
- IGHD | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 49/183 reads (27%) | catalogued as COSV101162955; called by muse, mutect2, varscan2
- IGHV3-7 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.837); catalogued as rs377399894; called by muse, varscan2
- IQCJ-SCHIP1 | c.974C>G p.T325S (on ENST00000485419 / NM_001197113.1; = p.T249S on NM_014575.3) | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1368457318; called by muse, mutect2, varscan2
- IRGC | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.395); catalogued as rs368220155; called by muse, mutect2, varscan2
- ITGA3 | c.2642G>A p.G881E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50308642, COSV50336764; called by muse, mutect2, varscan2
- ITPK1 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as COSV50899308; called by muse, mutect2, varscan2
- ITPR3 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 41/152 reads (27%) | catalogued as rs1174533195; called by muse, mutect2, varscan2
- KBTBD11 | c.1478C>A p.A493D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV57223118; called by muse, mutect2, varscan2
- KCNB2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73049334; called by muse, mutect2, varscan2
- KIRREL1 | c.1895G>C p.R632P | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.415); catalogued as COSV63285751; called by muse, mutect2, varscan2
- LHX8 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs772396075; called by mutect2, varscan2
- LPA | c.4612C>T p.P1538S | Missense Mutation (SNP) | VAF 82/599 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs1031642835; called by muse, mutect2, varscan2
- LPIN2 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 89/557 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1467998402, COSV54426166; called by muse, mutect2, varscan2
- LRIF1 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.408); catalogued as COSV63897038; called by muse, mutect2, varscan2
- MAPK4 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); catalogued as COSV101246084, COSV68541044; called by muse, mutect2, varscan2
- MDH1B | c.1424T>C p.V475A | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs371033736; called by muse, mutect2, varscan2
- MFAP3L | c.715A>G p.R239G | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356101904; called by muse, mutect2, varscan2
- MFSD11 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as rs749609248, COSV100334051, COSV60622332; called by muse, mutect2, varscan2
- MKRN3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs780006913, COSV58809891; called by muse, mutect2, varscan2
- MROH2A | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs577027731; called by muse, mutect2, varscan2
- MUC16 | c.3799C>T p.L1267F | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1405064242; called by muse, mutect2, varscan2
- MYO1B | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs368008917; called by muse, mutect2
- NCKAP5 | c.3026T>C p.M1009T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58449006; called by mutect2, varscan2
- NDUFB5 | c.343-2A>G p.X115_splice | Splice Site (SNP) | VAF 54/180 reads (30%) | catalogued as rs1305503687; called by muse, mutect2, varscan2
- NDUFC2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 84/420 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778952861, COSV55247188; called by muse, varscan2
- NELL1 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1021282447, COSV54257127; called by muse, mutect2, varscan2
- NFATC2 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1037062260, COSV65356179; called by muse, mutect2, varscan2
- NIPA2 | c.948C>G p.D316E | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV100487540; called by muse, mutect2
- NLRP12 | c.1074G>C p.R358S | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756377601; called by muse, mutect2, varscan2
- NPAS2 | c.1817T>A p.I606K | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV59556306; called by muse, mutect2, varscan2
- NTRK3 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as rs752675785, COSV58107778; called by muse, mutect2, varscan2
- OR10Q1 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs531710319, COSV57471205; called by muse, mutect2, varscan2
- OR11H12 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV73543697; called by muse, mutect2, varscan2
- OR2L2 | c.619G>T p.V207L | Missense Mutation (SNP) | VAF 159/483 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs749535493, COSV99057451; called by muse, mutect2, varscan2
- OR9G4 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 71/532 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs137994084; called by muse, mutect2, varscan2
- PCDH15 | c.5098C>T p.H1700Y | Missense Mutation (SNP) | VAF 66/536 reads (12%) | SIFT tolerated, low confidence (0.28); catalogued as rs375319155; called by muse, mutect2, varscan2
- PCDHB10 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 93/427 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.764); catalogued as rs782213344, COSV53378331, COSV99503661; called by muse, mutect2, varscan2
- PIEZO2 | c.2132A>T p.Y711F | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57440006; called by muse, mutect2
- PKHD1L1 | c.12058G>T p.E4020* | Nonsense Mutation (SNP) | VAF 33/251 reads (13%) | catalogued as COSV65750218; called by muse, mutect2, varscan2
- PKP3 | c.2159A>G p.N720S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs376598155; called by muse, mutect2, varscan2
- PLEKHG7 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV100760147; called by muse, mutect2
- PSG5 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 76/328 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV61655492; called by muse, mutect2, varscan2
- PTCH1 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs900926173; called by muse, mutect2, varscan2
- RB1 | c.2390T>G p.L797* | Nonsense Mutation (SNP) | VAF 73/359 reads (20%) | catalogued as CM023820, COSV57317102, COSV57328972; called by muse, mutect2, varscan2
- RGS20 | c.507G>T p.M169I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1352594774; called by muse, mutect2
- RGS4 | c.382A>T p.N128Y | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63357811; called by muse, varscan2
- RPAP3 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 72/424 reads (17%) | catalogued as rs757218659, COSV50042765; called by muse, mutect2, varscan2
- RRBP1 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs765455123; called by muse, mutect2
- RUNX1T1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56144761; called by muse, mutect2, varscan2
- SALL2 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV58103541; called by muse, mutect2, varscan2
- SCRIB | c.3808G>A p.A1270T | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs377531130; called by muse, mutect2, varscan2
- SGK1 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs746345368; called by muse, mutect2, varscan2
- SI | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 121/731 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015644; called by muse, mutect2, varscan2
- SIRPD | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV67546946; called by muse, mutect2, varscan2
- SLC25A53 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62458357; called by muse, mutect2, varscan2
- SMR3B | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as COSV59228664; called by muse, mutect2, varscan2
- SNTG1 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 90/605 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1169417602; called by muse, mutect2, varscan2
- SPATA31D1 | c.2245G>T p.A749S | Missense Mutation (SNP) | VAF 85/669 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs200798404; called by muse, mutect2, varscan2
- SPATA31D4 | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs754705400; called by mutect2, varscan2
- SPHKAP | c.2918A>C p.N973T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV60877468; called by muse, mutect2, varscan2
- STAP1 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV55329502; called by muse, mutect2, varscan2
- STAT5B | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 67/542 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs778995803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVEP1 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.266); catalogued as rs77339128, COSV99044081; called by muse, mutect2
- TBX21 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.368); catalogued as COSV51597276; called by muse, mutect2, varscan2
- TCF20 | c.4936G>A p.V1646I | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.672); catalogued as rs144324603; called by muse, mutect2, varscan2
- TEX14 | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV53614235; called by muse, mutect2, varscan2
- THSD7B | c.1765C>G p.P589A | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55675625, COSV99747110; called by muse, mutect2, varscan2
- TMEM117 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); catalogued as rs771506099, COSV56902960; called by mutect2, varscan2
- TMEM132D | c.1256A>C p.Y419S | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV70596941; called by muse, mutect2, varscan2
- TRAPPC9 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 122/738 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs201077904; called by muse, mutect2, varscan2
- TRIM48 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 60/461 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.728); catalogued as rs1035934795; called by muse, mutect2, varscan2
- TTN | c.86806G>A p.D28936N (on ENST00000591111; = p.D21512N on NM_003319.4) | Missense Mutation (SNP) | VAF 38/334 reads (11%) | PolyPhen benign (0.172); catalogued as rs781699152; called by muse, mutect2, varscan2
- TTN | c.53735G>A p.R17912Q (on ENST00000591111; = p.R10488Q on NM_003319.4) | Missense Mutation (SNP) | VAF 70/552 reads (13%) | PolyPhen benign (0.049); catalogued as rs543279513, COSV59935723; ClinVar: uncertain significance; called by muse, varscan2
- TTN | c.47258T>A p.L15753H (on ENST00000591111; = p.L8329H on NM_003319.4) | Missense Mutation (SNP) | VAF 97/579 reads (17%) | PolyPhen probably damaging (0.988); catalogued as COSV59912850; called by muse, mutect2, varscan2
- TTN | c.34769C>A p.P11590H (on ENST00000591111; = p.P10663H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/444 reads (19%) | PolyPhen possibly damaging (0.664); catalogued as rs924318627; called by muse, mutect2, varscan2
- TTN | c.17113G>A p.D5705N (on ENST00000591111; = p.D4778N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | PolyPhen benign (0.022); catalogued as rs767465221; called by muse, mutect2
- TXNRD3 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 102/1062 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553317981; called by muse, mutect2
- UBE2NL | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs781819629; called by muse, mutect2, varscan2
- USP17L2 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 131/1629 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV61556181; called by muse, mutect2
- UTRN | c.3850G>T p.A1284S | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as COSV62331114; called by muse, mutect2, varscan2
- VN1R4 | c.228T>A p.N76K | Missense Mutation (SNP) | VAF 60/432 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs1186773216; called by muse, mutect2, varscan2
- WFS1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.172); catalogued as rs138771366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFAT | c.1316A>T p.H439L | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64747640; called by muse, mutect2, varscan2
- ZNF415 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as COSV54699360; called by muse, mutect2, varscan2
- ZNF560 | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56867128; called by muse, mutect2, varscan2
- ZNF735 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 104/634 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1425248390; called by muse, mutect2, varscan2
- ZNF773 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 32/131 reads (24%) | catalogued as COSV56590326; called by muse, mutect2, varscan2
- ABCA13 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ACAN | c.2078C>A p.S693* | Nonsense Mutation (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- ACTR3B | c.1011G>T p.R337S | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM19 | c.983T>A p.V328D | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS7 | c.2710G>T p.A904S | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADCY1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ADGRD1 | c.2528T>G p.L843R | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AGRN | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AKNA | c.2722G>T p.G908C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AKR1C8P | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMDHD2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ANK2 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 72/601 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKEF1 | c.2087T>A p.V696E | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD26P1 | n.40A>C | Splice Region (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- ANKRD66 | c.207A>T p.Q69H | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ANKZF1 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANO4 | c.1489G>C p.D497H (on ENST00000392977 / NM_001286615.2; = p.D462H on NM_178826.4) | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- APOB | c.4557C>A p.N1519K | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ARID1A | c.3827G>T p.R1276L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARMH4 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 67/451 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ASAP1 | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASPSCR1 | c.1089G>T p.R363= | Splice Region (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- ATAD2B | c.1281A>T p.E427D | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ATP8A2 | c.241T>G p.L81V | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATR | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AUTS2 | c.1065G>C p.Q355H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- AXDND1 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 76/596 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXDND1 | c.1255T>A p.L419M | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- B3GALT2 | c.461T>A p.I154K | Missense Mutation (SNP) | VAF 82/512 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- C10orf67 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.011); called by muse, mutect2
- CABS1 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CAPRIN2 | c.1678A>G p.T560A | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD6 | c.1687A>G p.K563E | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CBLN3 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CCDC136 | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC14 | c.942G>T p.L314F (on ENST00000488653; = p.L266F on NM_022757.5) | Missense Mutation (SNP) | VAF 133/643 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CCDC170 | c.1307T>A p.L436Q | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CD177 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2
- CD209 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 77/659 reads (12%) | called by muse, varscan2
- CEACAM5 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CERCAM | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CFAP47 | c.7510G>T p.D2504Y | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CFHR4 | c.97C>A p.L33I (on ENST00000367416 / NM_001201551.2; = p.L34I on NM_006684.5) | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CHI3L1 | c.656A>T p.H219L | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CIT | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CLIP2 | c.2198A>T p.H733L | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLTC | c.4823C>G p.T1608R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.075); called by muse, varscan2
- CNTNAP4 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CP | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 56/380 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPSF1 | c.2488G>C p.G830R | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- CRISP1 | c.623-2A>T p.X208_splice | Splice Site (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- CSMD2 | c.6707T>A p.I2236N | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CTAGE4 | c.2132G>A p.R711K | Missense Mutation (SNP) | VAF 138/2176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- CTAGE9 | c.2132G>A p.R711K | Missense Mutation (SNP) | VAF 152/1141 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, varscan2
- CTIF | c.507+1G>T p.X169_splice | Splice Site (SNP) | VAF 47/298 reads (16%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.10359G>T p.L3453F | Missense Mutation (SNP) | VAF 103/644 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUX2 | c.2799C>A p.D933E | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX43 | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DDX60L | c.2300C>G p.T767R | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- DGAT2 | c.978del p.L327Wfs*41 | Frame Shift Del (DEL) | VAF 45/238 reads (19%) | called by mutect2, pindel, varscan2
- DIRAS2 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- DNAI4 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 146/563 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSEL | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 50/340 reads (15%) | called by muse, mutect2, varscan2
- DTD1 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DYNC2I1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.411); called by muse, varscan2
- EIF2B4 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 96/638 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- EIF2S3B | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 67/478 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ELF4 | c.541A>C p.T181P | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ERC1 | c.2819C>G p.A940G (on ENST00000360905 / NM_178040.4; = p.A912G on NM_178039.4) | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ESRRB | c.1224G>T p.Q408H | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- EVX2 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC6B | c.105del p.T36Rfs*44 | Frame Shift Del (DEL) | VAF 27/167 reads (16%) | called by mutect2, pindel, varscan2
- EYS | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FANCM | c.2090G>T p.S697I | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FASTKD5 | c.1726G>T p.V576F | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FBN2 | c.3245G>A p.G1082E | Missense Mutation (SNP) | VAF 103/556 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FBN2 | c.3244G>T p.G1082W | Missense Mutation (SNP) | VAF 103/559 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- FBXO15 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FGF5 | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 73/437 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- FPR3 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSIP2 | c.20672G>T p.C6891F | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRR3 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GNPAT | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 100/609 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GPR155 | c.2192A>C p.N731T | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2
- GPR158 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR37 | c.139A>C p.T47P | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GPRC5B | c.539G>T p.W180L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPRIN3 | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GRIK5 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP2 | c.1330C>G p.Q444E (on ENST00000619221; = p.Q347E on NM_001080423.4) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GRM3 | c.1997T>A p.I666N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTO1 | c.230del p.N77Tfs*6 | Frame Shift Del (DEL) | VAF 104/589 reads (18%) | called by mutect2, pindel, varscan2
- GSX1 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCY1A2 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, varscan2
- GZF1 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HEPH | c.2389C>A p.P797T (on ENST00000343002; = p.P530T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- HNF1B | c.803G>T p.C268F | Missense Mutation (SNP) | VAF 24/493 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- HRG | c.209T>A p.V70D | Missense Mutation (SNP) | VAF 117/569 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- HTRA4 | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 153/546 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- IGKV1D-17 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- INPP4A | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IPO11 | c.1787G>C p.R596P | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- IQGAP2 | c.3294+1G>C p.X1098_splice | Splice Site (SNP) | VAF 48/214 reads (22%) | called by muse, mutect2, varscan2
- IZUMO3 | c.86T>A p.I29K | Missense Mutation (SNP) | VAF 110/548 reads (20%) | SIFT tolerated (0.32); called by muse, mutect2, varscan2
- KCNA7 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- KCNH7 | c.2507T>A p.I836N | Missense Mutation (SNP) | VAF 89/540 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNQ3 | c.1263-1G>T p.X421_splice | Splice Site (SNP) | VAF 62/488 reads (13%) | called by mutect2, varscan2
- KIAA0319L | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA1549L | c.5032C>A p.L1678M (on ENST00000321505; = p.L1975M on NM_012194.3) | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KLHDC3 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL1 | c.2015+1G>T p.X672_splice | Splice Site (SNP) | VAF 41/178 reads (23%) | called by muse, mutect2, varscan2
- KLRF1 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2
- LIME1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- LONRF2 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 63/418 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC27 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MACF1 | c.21928G>T p.G7310W (on ENST00000372915; = p.G5355W on NM_012090.5) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- MARCHF6 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MBD5 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 86/671 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MDN1 | c.2332A>T p.K778* | Nonsense Mutation (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- MMP12 | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPEG1 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- MT1M | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- MTPAP | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 82/678 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MYO6 | c.3403G>T p.E1135* (on ENST00000369981; = p.E1125* on NM_004999.4) | Nonsense Mutation (SNP) | VAF 77/426 reads (18%) | called by muse, mutect2, varscan2
- NAPB | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NBEAL2 | c.2104G>C p.G702R | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL2 | c.2168G>T p.C723F | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NDST4 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- NEB | c.12870G>T p.E4290D | Missense Mutation (SNP) | VAF 70/486 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.287); called by muse, varscan2
- NEIL3 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NISCH | c.4130G>T p.S1377I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NKX1-2 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2
- NMU | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAP1 | c.2537A>T p.E846V | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.136); called by muse, mutect2
- NPHS1 | c.3095C>G p.P1032R | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPTN | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 77/348 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NUDT22 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR1A2 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 66/799 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- OR1N1 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 65/386 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- OR2M5 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 86/555 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- OR2T2 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 106/614 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR3A3 | c.307T>G p.Y103D | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR4C46 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- OR4C6 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5AR1 | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, varscan2
- OSBPL6 | c.1967A>G p.Y656C | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL6 | c.2267G>C p.S756T | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- OTOL1 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 182/637 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- OTUD5 | c.571A>T p.M191L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA2 | c.2396C>A p.P799Q | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PASK | c.3025G>A p.A1009T | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PCDH15 | c.705+1G>T p.X235_splice | Splice Site (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- PCSK1N | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PDE3A | c.2899G>C p.G967R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PEG3 | c.2967G>T p.K989N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PELP1 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PFKP | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 48/212 reads (23%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- PI4KB | c.2234A>T p.D745V (on ENST00000368873 / NM_001369623.1; = p.D757V on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- PIP | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.22); called by muse, mutect2
- PKHD1 | c.846C>A p.D282E | Missense Mutation (SNP) | VAF 112/498 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- PLEKHG4B | c.1520A>T p.Q507L (on ENST00000283426; = p.Q863L on NM_052909.5) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- PLXNC1 | c.3049G>T p.D1017Y | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXND1 | c.3407C>G p.P1136R | Missense Mutation (SNP) | VAF 35/452 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PNLIP | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- POTEE | c.2614_2615insA p.P872Hfs*16 | Frame Shift Ins (INS) | VAF 41/386 reads (11%) | called by mutect2, varscan2
- PROS1 | c.175A>T p.I59F | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPDC1 | c.877T>G p.C293G (on ENST00000375360 / NM_177995.3; = p.C345G on NM_152422.4) | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PTPRF | c.5247C>G p.C1749W | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.1686A>T p.E562D | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PYGM | c.1334T>A p.L445Q | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PZP | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- RAB3IL1 | c.928A>T p.T310S | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABGAP1L | c.2313A>T p.R771S | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RB1CC1 | c.2404A>G p.R802G | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RELN | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 61/541 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- REPS2 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- RERGL | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- RGS22 | c.1387A>T p.S463C | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIN3 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RNF112 | c.1220A>T p.Y407F | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RPUSD2 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RYR2 | c.9457T>A p.S3153T | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SAMD7 | c.977A>C p.K326T | Missense Mutation (SNP) | VAF 83/509 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SATL1 | c.825C>A p.S275R (on ENST00000395409; = p.S462R on NM_001012980.2) | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SCG5 | c.575T>A p.L192Q (on ENST00000300175 / NM_001144757.2; = p.L191Q on NM_003020.4) | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN4A | c.2792C>A p.S931Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, varscan2
- SCN5A | c.5671C>A p.P1891T (on ENST00000333535 / NM_198056.3; = p.P1890T on NM_000335.5) | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCN7A | c.2618A>C p.E873A | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN9A | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- SEMA5A | c.2370G>A p.W790* | Nonsense Mutation (SNP) | VAF 94/577 reads (16%) | called by muse, mutect2, varscan2
- SENP7 | c.2023A>T p.I675F | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- SLC12A8 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 208/779 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- SLC30A8 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC4A4 | c.1358_1361dup p.P455Sfs*7 (on ENST00000264485 / NM_001098484.3; = p.P411Sfs*7 on NM_003759.4) | Frame Shift Ins (INS) | VAF 38/318 reads (12%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.952T>C p.F318L | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLCO5A1 | c.656C>A p.S219* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1793C>A p.T598K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLITRK3 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMCR8 | c.2567C>T p.S856F | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- SPAM1 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 75/529 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPATA31E1 | c.3700G>T p.A1234S | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SPATA7 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SPIN1 | c.51A>C p.A17= | Splice Region (SNP) | VAF 71/458 reads (16%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2762del p.P921Qfs*139 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel
- SPTA1 | c.2455A>T p.T819S | Missense Mutation (SNP) | VAF 65/489 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SSBP3 | c.488dup p.I164Dfs*75 | Frame Shift Ins (INS) | VAF 19/162 reads (12%) | called by mutect2, pindel, varscan2
- SSUH2 | c.33A>T p.L11F | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST6GALNAC2 | c.774-7G>T | Splice Region (SNP) | VAF 45/208 reads (22%) | called by muse, mutect2, varscan2
- SUV39H2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- SVEP1 | c.2886G>T p.M962I | Missense Mutation (SNP) | VAF 79/585 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TBCD | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- TEX11 | c.1667T>A p.I556N (on ENST00000344304; = p.I541N on NM_031276.3) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TFRC | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 122/728 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM135 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TMEM151A | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TMEM168 | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TMTC2 | c.11A>T p.E4V | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMX4 | c.116T>A p.V39D | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TNPO2 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TNS1 | c.4792G>C p.A1598P | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TNS3 | c.3012del p.A1005Qfs*51 | Frame Shift Del (DEL) | VAF 73/355 reads (21%) | called by mutect2, pindel, varscan2
- TP53 | c.837dup p.R280Efs*26 | Frame Shift Ins (INS) | VAF 86/571 reads (15%) | called by mutect2, pindel, varscan2
- TRABD2A | c.1078C>T p.H360Y (on ENST00000409520 / NM_001277053.2; = p.H311Y on NM_001080824.3) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by mutect2, varscan2
- TRIM37 | c.2890A>T p.R964W | Missense Mutation (SNP) | VAF 81/569 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TRIM60 | c.1156T>C p.W386R | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM8 | c.1654G>T p.D552Y | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TSC22D4 | c.979-5C>G | Splice Region (SNP) | VAF 53/235 reads (23%) | called by muse, mutect2, varscan2
- TTC17 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 49/407 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TUT7 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- UBE2NL | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- VN1R5 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS13D | c.9747G>A p.M3249I | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VSTM2B | c.268-1G>T p.X90_splice | Splice Site (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- VWC2L | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 33/297 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR87 | c.4845A>T p.K1615N | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- WT1 | c.1402A>T p.S468C | Missense Mutation (SNP) | VAF 111/646 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ZBED5 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZBTB11 | c.1342A>G p.S448G | Missense Mutation (SNP) | VAF 123/557 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFYVE26 | c.5411_5439del p.P1804Hfs*2 | Frame Shift Del (DEL) | VAF 56/425 reads (13%) | called by mutect2, pindel
- ZNF296 | c.1156_1157dup p.S387Afs*16 | Frame Shift Ins (INS) | VAF 54/337 reads (16%) | called by mutect2, pindel, varscan2
- ZNF469 | c.5353G>T p.G1785W (on ENST00000437464; = p.G1813W on NM_001367624.2) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZSCAN1 | c.467_468dup p.S157Rfs*4 | Frame Shift Ins (INS) | VAF 53/209 reads (25%) | called by mutect2, pindel, varscan2
- AC013489.1 | c.1203C>G p.T401= | Silent (SNP) | VAF 29/151 reads (19%) | called by muse, mutect2, varscan2
- ADCY10 | c.2055C>T p.A685= | Silent (SNP) | VAF 118/349 reads (34%) | catalogued as rs758043012, COSV63243092; called by muse, mutect2, varscan2
- ADCY7 | c.480G>T p.L160= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.30G>C p.L10= | Silent (SNP) | VAF 36/517 reads (7%) | called by muse, mutect2
- ANK1 | c.5421G>T p.G1807= | Silent (SNP) | VAF 111/729 reads (15%) | called by muse, mutect2, varscan2
- ANKRD33B | c.1224C>G p.P408= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- ANKUB1 | c.1482A>G p.A494= | Silent (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- APOBEC3H | c.387C>A p.S129= | Silent (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
- ARAP2 | c.2745G>T p.L915= | Silent (SNP) | VAF 54/278 reads (19%) | called by muse, mutect2, varscan2
- ATP2C1 | c.1068G>A p.T356= | Silent (SNP) | VAF 33/359 reads (9%) | catalogued as rs1361815539, COSV60762775; called by muse, mutect2, varscan2
- BAIAP3 | c.117G>A p.L39= | Silent (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- BMP15 | c.354C>A p.G118= | Silent (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- C10orf90 | c.1326G>A p.Q442= | Silent (SNP) | VAF 27/231 reads (12%) | called by muse, mutect2, varscan2
- C6 | c.1935T>A p.P645= | Silent (SNP) | VAF 95/580 reads (16%) | called by muse, mutect2, varscan2
- C6 | c.1443T>A p.A481= | Silent (SNP) | VAF 66/471 reads (14%) | called by muse, mutect2, varscan2
- CALD1 | c.399A>T p.P133= | Silent (SNP) | VAF 40/181 reads (22%) | called by muse, mutect2, varscan2
- CBX7 | c.540A>G p.P180= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- CCDC14 | c.75C>A p.P25= | Silent (SNP) | VAF 80/367 reads (22%) | called by muse, mutect2, varscan2
- CFAP52 | c.1107G>T p.R369= | Silent (SNP) | VAF 57/333 reads (17%) | called by muse, mutect2, varscan2
- CRB1 | c.3618C>T p.Y1206= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV66329189; called by muse, mutect2
- CUBN | c.27T>A p.L9= | Silent (SNP) | VAF 106/751 reads (14%) | called by muse, mutect2, varscan2
- DAAM2 | c.129G>T p.P43= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs370984960; called by muse, mutect2, varscan2
- DGKI | c.1653A>G p.P551= | Silent (SNP) | VAF 39/257 reads (15%) | catalogued as rs373135185; called by muse, mutect2, varscan2
- ENPP1 | c.1902G>A p.P634= | Silent (SNP) | VAF 80/786 reads (10%) | catalogued as rs116072046; called by muse, mutect2, varscan2
- FA2H | c.384G>A p.K128= | Silent (SNP) | VAF 95/404 reads (24%) | catalogued as rs925293378; called by muse, mutect2, varscan2
- FAM184A | c.654G>A p.K218= | Silent (SNP) | VAF 34/268 reads (13%) | called by muse, mutect2, varscan2
- FAM186A | c.2397A>T p.I799= | Silent (SNP) | VAF 61/327 reads (19%) | called by muse, mutect2, varscan2
- FAM43A | c.60G>C p.A20= | Silent (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2
- FCGRT | c.858C>G p.L286= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- GABRG1 | c.168C>A p.A56= | Silent (SNP) | VAF 27/259 reads (10%) | catalogued as COSV54955990; called by muse, mutect2, varscan2
- GDF6 | c.1122G>T p.A374= | Silent (SNP) | VAF 110/639 reads (17%) | catalogued as COSV54625176; called by muse, mutect2, varscan2
- GNAI1 | c.531T>A p.T177= | Silent (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
- GRIN3A | c.270G>T p.A90= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- HGD | c.1326A>G p.A442= | Silent (SNP) | VAF 47/593 reads (8%) | catalogued as COSV99381462; called by muse, mutect2
- IL12RB2 | c.129T>C p.L43= | Silent (SNP) | VAF 72/324 reads (22%) | called by muse, mutect2, varscan2
- ITPR3 | c.738G>T p.A246= | Silent (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- JAML | c.141A>G p.T47= (on ENST00000356289 / NM_001098526.2; = p.T37= on NM_153206.3) | Silent (SNP) | VAF 56/265 reads (21%) | called by muse, mutect2, varscan2
- KAT6A | c.855C>T p.D285= | Silent (SNP) | VAF 81/662 reads (12%) | catalogued as rs867297189, COSV55911112; called by muse, mutect2, varscan2
- KCNMA1 | c.3643C>A p.R1215= (on ENST00000286628 / NM_001161352.2; = p.R1157= on NM_002247.4) | Silent (SNP) | VAF 178/648 reads (27%) | called by muse, mutect2, varscan2
- KLHDC3 | c.381C>T p.A127= | Silent (SNP) | VAF 54/358 reads (15%) | called by muse, mutect2, varscan2
- KLHL1 | c.2085C>G p.V695= | Silent (SNP) | VAF 49/337 reads (15%) | catalogued as rs377213465, COSV100917719, COSV64772173, COSV64784616; called by muse, mutect2, varscan2
- KRTAP7-1 | c.171T>A p.G57= | Silent (SNP) | VAF 94/630 reads (15%) | called by muse, mutect2
- LRFN5 | c.1872C>A p.T624= | Silent (SNP) | VAF 113/561 reads (20%) | called by muse, mutect2, varscan2
- LRP6 | c.1962G>C p.V654= | Silent (SNP) | VAF 58/444 reads (13%) | called by muse, mutect2, varscan2
- LRRK2 | c.1443A>T p.A481= | Silent (SNP) | VAF 77/654 reads (12%) | called by muse, mutect2, varscan2
- MCHR2 | c.282C>A p.A94= | Silent (SNP) | VAF 70/437 reads (16%) | called by muse, mutect2, varscan2
- MDC1 | c.561A>G p.T187= | Silent (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- MLLT10 | c.861A>G p.A287= | Silent (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- MMP20 | c.636T>A p.T212= | Silent (SNP) | VAF 96/516 reads (19%) | called by muse, mutect2, varscan2
- MYH2 | c.1413T>C p.F471= | Silent (SNP) | VAF 70/800 reads (9%) | called by muse, mutect2
- NAV1 | c.4119G>A p.Q1373= | Silent (SNP) | VAF 73/357 reads (20%) | catalogued as rs781073209; called by muse, mutect2, varscan2
- NCKAP1L | c.3195C>A p.V1065= | Silent (SNP) | VAF 62/335 reads (19%) | called by muse, mutect2, varscan2
- NCKAP5 | c.4054C>T p.L1352= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- NUP210 | c.5031C>T p.S1677= | Silent (SNP) | VAF 87/368 reads (24%) | called by muse, mutect2, varscan2
- OAS3 | c.1110G>A p.K370= | Silent (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- OLIG3 | c.585G>A p.S195= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV100880316; called by muse, mutect2, varscan2
- OR1B1 | c.330G>T p.G110= | Silent (SNP) | VAF 18/366 reads (5%) | called by muse, mutect2
- OR8G1 | c.276C>A p.I92= | Silent (SNP) | VAF 79/497 reads (16%) | catalogued as rs1195308053; called by muse, mutect2, varscan2
- PAN3 | c.729A>G p.L243= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as rs766569962; called by muse, mutect2, varscan2
- PCDH15 | c.3558A>G p.P1186= | Silent (SNP) | VAF 58/525 reads (11%) | called by muse, mutect2, varscan2
- PLCB1 | c.3624A>T p.P1208= | Silent (SNP) | VAF 67/308 reads (22%) | called by muse, mutect2, varscan2
- PLXNA1 | c.1162C>T p.L388= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- POLR2A | c.5772G>C p.S1924= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- POTEF | c.861C>T p.V287= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs3100067; called by mutect2, varscan2
- RYR1 | c.1995G>A p.V665= | Silent (SNP) | VAF 63/376 reads (17%) | called by muse, varscan2
- RYR1 | c.12552C>A p.G4184= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV62094427; called by muse, mutect2, varscan2
- SERPINB9 | c.642G>T p.A214= | Silent (SNP) | VAF 44/233 reads (19%) | called by muse, mutect2, varscan2
- SLC12A8 | c.498G>C p.L166= | Silent (SNP) | VAF 206/781 reads (26%) | called by muse, mutect2, varscan2
- SMIM10 | c.213C>T p.A71= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- SNRNP200 | c.1590C>T p.T530= | Silent (SNP) | VAF 106/538 reads (20%) | called by muse, mutect2, varscan2
- TDRD15 | c.1983T>C p.Y661= | Silent (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- THSD7A | c.654G>T p.T218= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV70268842; called by muse, mutect2, varscan2
- TM9SF1 | c.1467A>T p.V489= | Silent (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- TMEM104 | c.279C>T p.A93= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- TMEM178B | c.462G>T p.T154= | Silent (SNP) | VAF 29/472 reads (6%) | catalogued as COSV101639573; called by muse, mutect2
- TMIGD2 | c.585C>A p.V195= | Silent (SNP) | VAF 141/321 reads (44%) | called by muse, mutect2, varscan2
- TMOD1 | c.441C>T p.Y147= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- TPO | c.1476C>T p.F492= | Silent (SNP) | VAF 12/310 reads (4%) | catalogued as rs756980159, COSV61102342; called by muse, mutect2
- TRABD2A | c.1077C>A p.I359= (on ENST00000409520 / NM_001277053.2; = p.I310= on NM_001080824.3) | Silent (SNP) | VAF 30/244 reads (12%) | called by muse, varscan2
- TRGC1 | c.18A>G p.A6= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs770240313; called by muse, varscan2
- TYK2 | c.420G>T p.G140= | Silent (SNP) | VAF 142/335 reads (42%) | called by muse, mutect2, varscan2
- USP14 | c.1245T>C p.C415= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV55273982; called by muse, mutect2, varscan2
- USP25 | c.3099G>T p.T1033= | Silent (SNP) | VAF 52/346 reads (15%) | catalogued as rs151062503, COSV53491589, COSV99584326; called by muse, varscan2
- VIT | c.1374G>A p.S458= (on ENST00000389975 / NM_001177969.1; = p.S473= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs746829069, COSV64898010; called by muse, mutect2, varscan2
- ZCCHC14 | c.1563G>T p.A521= (on ENST00000268616; = p.A658= on NM_015144.3) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV51888536; called by muse, mutect2, varscan2
- ZCCHC2 | c.3237A>G p.P1079= | Silent (SNP) | VAF 45/254 reads (18%) | called by muse, mutect2, varscan2
- AC025048.6 | n.214C>T | RNA (SNP) | VAF 34/244 reads (14%) | called by muse, mutect2
- AC068631.2 | chr3:186597159 C>A | 3'Flank (SNP) | VAF 86/769 reads (11%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9549C>G | Intron (SNP) | VAF 40/584 reads (7%) | called by muse, mutect2
- ACADL | c.371+23T>A | Intron (SNP) | VAF 70/397 reads (18%) | called by muse, mutect2, varscan2
- AK2 | c.*468A>G | 3'UTR (SNP) | VAF 12/71 reads (17%) | catalogued as rs1171578295; called by muse, mutect2, varscan2
- AL008638.2 | n.319C>A | RNA (SNP) | VAF 78/408 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850025 C>A | 5'Flank (SNP) | VAF 54/169 reads (32%) | called by muse, mutect2, varscan2
- AL772337.1 | n.857+181G>A | Intron (SNP) | VAF 59/329 reads (18%) | called by muse, mutect2, varscan2
- ANO9 | c.407-17G>T | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- ATG2B | chr14:96276081 C>A | 3'Flank (SNP) | VAF 33/216 reads (15%) | called by muse, mutect2, varscan2
- ATP13A1 | c.396+49G>T | Intron (SNP) | VAF 39/107 reads (36%) | catalogued as rs1319229138; called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48109T>A | Intron (SNP) | VAF 99/430 reads (23%) | called by muse, varscan2
- BLM | c.4077-43G>T | Intron (SNP) | VAF 12/110 reads (11%) | catalogued as rs1187489374; called by muse, mutect2, varscan2
- C14orf132 | chr14:96090785 G>A | 3'Flank (SNP) | VAF 42/184 reads (23%) | catalogued as rs914818606, COSV101402393; called by muse, mutect2, varscan2
- CACNA1B | c.530+9222A>G | Intron (SNP) | VAF 33/289 reads (11%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.2107-51G>C | Intron (SNP) | VAF 55/399 reads (14%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10381G>T | Intron (SNP) | VAF 85/607 reads (14%) | called by muse, mutect2, varscan2
- CHRM2 | c.-47+33844T>A | Intron (SNP) | VAF 50/374 reads (13%) | called by muse, mutect2, varscan2
- CLK4 | c.161+9_161+31del | Intron (DEL) | VAF 36/233 reads (15%) | called by mutect2, pindel, varscan2
- DES | c.-33C>T | 5'UTR (SNP) | VAF 24/114 reads (21%) | catalogued as rs1310430106; called by muse, mutect2, varscan2
- DOCK4 | c.1066+72G>T | Intron (SNP) | VAF 67/554 reads (12%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.2402-735G>C | Intron (SNP) | VAF 42/322 reads (13%) | called by muse, mutect2, varscan2
- EP400P1 | n.1118del | RNA (DEL) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- FOLH1B | n.1643A>T | RNA (SNP) | VAF 74/608 reads (12%) | called by muse, mutect2, varscan2
- GDPD2 | c.*11C>T | 3'UTR (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.*123G>T | 3'UTR (SNP) | VAF 24/223 reads (11%) | called by muse, mutect2, varscan2
- GPR161 | chr1:168084949 G>A | 3'Flank (SNP) | VAF 100/496 reads (20%) | catalogued as rs1169165448; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1641C>T | RNA (SNP) | VAF 82/463 reads (18%) | catalogued as rs1554532735; called by muse, varscan2
- GVINP1 | n.6397G>A | RNA (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- GVINP1 | n.6396G>A | RNA (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- HBS1L | c.430+2843G>T | Intron (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- HMGN3 | c.261+168C>A | Intron (SNP) | VAF 34/237 reads (14%) | called by muse, mutect2, varscan2
- KCNJ8 | c.375-33G>T | Intron (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- KLRD1 | c.7+35C>G | Intron (SNP) | VAF 43/227 reads (19%) | called by muse, mutect2, varscan2
- LINC00917 | n.1493G>T | RNA (SNP) | VAF 48/252 reads (19%) | called by muse, mutect2, varscan2
- MYH15 | c.-3A>T | 5'UTR (SNP) | VAF 23/245 reads (9%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.*1097T>A | 3'UTR (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- NRBF2 | c.-115G>A | 5'UTR (SNP) | VAF 24/106 reads (23%) | called by mutect2, varscan2
- NUDT16 | c.*88G>T | 3'UTR (SNP) | VAF 51/190 reads (27%) | catalogued as rs1043583001; called by muse, mutect2, varscan2
- OR4N3P | n.809T>A | RNA (SNP) | VAF 26/221 reads (12%) | called by muse, mutect2
- PGAM5P1 | chr5:109884439 C>A | 3'Flank (SNP) | VAF 64/372 reads (17%) | called by muse, mutect2, varscan2
- PMPCA | c.1408+162G>T | Intron (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | chr19:10106317 C>A | 5'Flank (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- RAB5B | c.*257A>G | 3'UTR (SNP) | VAF 31/202 reads (15%) | called by muse, mutect2, varscan2
- REXO1L1P | n.769C>A | RNA (SNP) | VAF 30/914 reads (3%) | called by muse, mutect2
- RNU7-174P | chr8:80559309 T>A | 5'Flank (SNP) | VAF 134/709 reads (19%) | called by mutect2, varscan2
- RUFY2 | c.-58C>A | 5'UTR (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- SOX8 | chr16:976911 G>T | 5'Flank (SNP) | VAF 49/190 reads (26%) | catalogued as rs757802509; called by muse, mutect2, varscan2
- SRRM2-AS1 | n.384C>T | RNA (SNP) | VAF 67/341 reads (20%) | called by muse, mutect2, varscan2
- STK24-AS1 | chr13:98576753 C>A | 5'Flank (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- SYNE1 | c.4461+34G>A | Intron (SNP) | VAF 36/251 reads (14%) | catalogued as rs767793172; called by muse, mutect2, varscan2
- TMC1 | c.*67A>T | 3'UTR (SNP) | VAF 58/374 reads (16%) | called by muse, varscan2
- TNNT3 | c.714+50A>T | Intron (SNP) | VAF 39/161 reads (24%) | called by muse, mutect2, varscan2
- TTC31 | c.876+72G>A | Intron (SNP) | VAF 21/89 reads (24%) | called by muse, varscan2
- TTN | c.10361-3851C>T | Intron (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10361-5093C>A | Intron (SNP) | VAF 28/181 reads (15%) | called by muse, mutect2, varscan2
- UBE2V2 | c.16+11G>T | Intron (SNP) | VAF 46/243 reads (19%) | catalogued as rs777021338; called by muse, mutect2, varscan2
- VAPB | c.*1162G>T | 3'UTR (SNP) | VAF 36/319 reads (11%) | called by muse, mutect2, varscan2
- VEPH1 | c.138+6086A>C | Intron (SNP) | VAF 78/439 reads (18%) | called by muse, mutect2, varscan2
- VPS41 | c.2404+127G>T | Intron (SNP) | VAF 48/341 reads (14%) | called by muse, mutect2, varscan2
- WDR86 | chr7:151411731 C>A | 5'Flank (SNP) | VAF 32/186 reads (17%) | called by muse, varscan2
- WFDC3 | c.*30T>A | 3'UTR (SNP) | VAF 46/263 reads (17%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.994-32G>T | Intron (SNP) | VAF 45/212 reads (21%) | catalogued as rs373670707; called by muse, mutect2, varscan2
- ZNF733P | n.332_333del | RNA (DEL) | VAF 47/362 reads (13%) | called by mutect2, pindel, varscan2
- ZNF813 | c.142+1533G>T | Intron (SNP) | VAF 40/245 reads (16%) | called by muse, mutect2, varscan2
